Somatic mutation profile of tumor specimen MMRF_1354_1_BM_CD138pos (aliquot MMRF_1354_1_BM_CD138pos_T1_KAS5U_L00641) from MMRF case MMRF_1354, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.4 years (27,527 days).
Specimen MMRF_1354_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f7e4009-3cb7-4642-96d1-14aa3ac303c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1354_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1354_1_PB_Whole_C2_KAS5U_L00649; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d905ef9-e84b-4891-a26f-6eed355a0d3a

The open-access MAF lists 123 somatic variants for this specimen: 41 protein-altering or splice-affecting, 24 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 30, Silent 24, Intron 11, 5'UTR 8, RNA 6, Splice Site 3, Splice Region 2, Frame Shift Del 2, 3'Flank 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY9 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV53573279; called by muse, mutect2, varscan2
- ALDOB | c.187del p.L63Sfs*15 | Frame Shift Del (DEL) | VAF 11/56 reads (20%) | catalogued as COSV66397883; called by mutect2, pindel*, varscan2*
- BEGAIN | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs1225779940, COSV62069306; called by muse, mutect2, varscan2
- BMP2 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs759121274, COSV66579311; called by muse, mutect2, varscan2
- CDH15 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99228363, COSV99228947; called by muse, mutect2, varscan2
- CTDSPL | c.796G>A p.V266M (on ENST00000273179 / NM_001008392.2; = p.V255M on NM_005808.3) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs566199681; called by muse, mutect2, varscan2
- CYP20A1 | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs762579762; called by muse, mutect2, varscan2
- DNAH7 | c.6688A>G p.I2230V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1402780945; called by muse, mutect2, varscan2
- DPYSL4 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200567895; called by muse, mutect2, varscan2
- HMBS | c.206C>G p.S69C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as CD972255; called by muse, mutect2, varscan2
- IGHD6-25 | c.4T>G p.Y2D | Missense Mutation (SNP) | VAF 21/21 reads (100%) | catalogued as rs554117752; called by muse, mutect2, varscan2
- IGHV2-70 | c.220T>C p.W74R | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.688); catalogued as rs375052259; called by muse, varscan2
- IGHV4-34 | c.183C>G p.S61R | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as rs11546809; called by muse, mutect2, varscan2
- IGHV4-34 | c.97T>C p.W33R | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs587598533; called by muse, mutect2, varscan2
- IGLV3-1 | c.165G>T p.Q55H | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs137930227; called by muse, varscan2
- KIAA1549 | c.860C>G p.S287C | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs369303006, COSV104386768; called by muse, mutect2, varscan2
- LILRB4 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1375911983, COSV54409868, COSV99553868; called by muse, mutect2, varscan2
- LTK | c.2221C>T p.R741W | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (1); catalogued as rs370375739; called by muse, mutect2, varscan2
- OR5L2 | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65723659, COSV65725420; called by mutect2, varscan2
- PCDHA4 | c.487G>T p.G163W | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782061737, COSV100793314; called by muse, mutect2, varscan2
- PDE4DIP | c.829C>G p.Q277E | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV57707000; called by muse, mutect2, varscan2
- PDE4DIP | c.982-3C>T | Splice Region (SNP) | VAF 16/46 reads (35%) | catalogued as rs1553512537; called by muse, mutect2, varscan2
- POP1 | c.143-2A>G p.X48_splice | Splice Site (SNP) | VAF 25/48 reads (52%) | catalogued as rs780982639; called by muse, mutect2, varscan2
- RHOV | c.569C>A p.T190K | Missense Mutation (SNP) | VAF 48/79 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55028015; called by muse, mutect2, varscan2
- RIN2 | c.59C>A p.T20K | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.036); catalogued as rs1179471753, COSV54790214; called by muse, mutect2, varscan2
- SNRNP200 | c.5762G>A p.R1921Q | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as rs1354326901; called by muse, mutect2, varscan2
- URB1 | c.2106+1G>A p.X702_splice | Splice Site (SNP) | VAF 54/84 reads (64%) | catalogued as rs956463531; called by muse, mutect2, varscan2
- ZNF470 | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs370650023, COSV100401065; called by muse, mutect2, varscan2
- ADGRF2 | c.1130T>C p.I377T (on ENST00000296862 / NM_001368115.2; = p.I309T on NM_153839.7) | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- AGAP2 | c.1834C>G p.L612V (on ENST00000547588 / NM_001122772.2; = p.L276V on NM_014770.4) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- ANK1 | c.3632T>G p.F1211C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CDCP1 | c.905C>G p.P302R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DUSP2 | c.511-8C>G | Splice Region (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- FIP1L1 | c.706-2A>G p.X236_splice | Splice Site (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- FSIP2 | c.12001T>C p.S4001P | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MAGI2 | c.1765G>T p.D589Y | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MPP5 | c.215A>G p.E72G | Missense Mutation (SNP) | VAF 4/95 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- NBAS | c.2152A>G p.K718E | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.091); called by muse, mutect2
- PARP9 | c.349A>G p.R117G | Missense Mutation (SNP) | VAF 54/83 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGBD4 | c.53T>G p.L18R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- TET2 | c.2109_2122del p.L703Ffs*4 | Frame Shift Del (DEL) | VAF 31/103 reads (30%) | called by mutect2, pindel, varscan2
- ALX4 | c.153C>T p.A51= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- ANO9 | c.1384C>T p.L462= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs751011362; called by muse, mutect2, varscan2
- BHLHE22 | c.879C>T p.I293= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100417756; called by muse, mutect2, varscan2
- CHST7 | c.51G>A p.L17= | Silent (SNP) | VAF 12/12 reads (100%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.7656A>G p.L2552= | Silent (SNP) | VAF 12/16 reads (75%) | called by muse, mutect2, varscan2
- GNA15 | c.153C>T p.G51= | Silent (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- HUNK | c.2034T>C p.S678= | Silent (SNP) | VAF 37/111 reads (33%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.75G>A p.E25= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs181122105; called by muse, varscan2
- IGLL5 | c.123A>G p.P41= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs531175408, COSV73250509; called by muse, mutect2, varscan2
- IGLV4-3 | c.189C>G p.P63= | Silent (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2, varscan2
- LRCH2 | c.168C>T p.F56= | Silent (SNP) | VAF 14/14 reads (100%) | catalogued as COSV100406987; called by muse, mutect2, varscan2
- LRFN4 | c.1401C>T p.G467= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs189468338; called by muse, mutect2, varscan2
- MC5R | c.519C>T p.C173= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as rs760716663, COSV61254939; called by muse, mutect2, varscan2
- MTUS1 | c.105T>A p.P35= | Silent (SNP) | VAF 42/61 reads (69%) | called by muse, mutect2, varscan2
- PDZRN3 | c.2394G>A p.T798= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs373980614; called by muse, mutect2, varscan2
- PI16 | c.282C>T p.D94= | Silent (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- POLD2 | c.501C>T p.D167= | Silent (SNP) | VAF 37/103 reads (36%) | catalogued as rs772704615; called by muse, mutect2, varscan2
- PROSER2 | c.666C>T p.P222= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs759686403; called by muse, mutect2, varscan2
- RP1 | c.2853T>C p.S951= | Silent (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- SLC16A4 | c.1141C>T p.L381= | Silent (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- STX8 | c.444C>T p.I148= | Silent (SNP) | VAF 34/69 reads (49%) | called by muse, mutect2, varscan2
- SYBU | c.1602G>A p.E534= (on ENST00000276646 / NM_001099754.2; = p.E533= on NM_017786.6) | Silent (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2, varscan2
- ZNF219 | c.1479G>T p.R493= | Silent (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- ZNF330 | c.822G>A p.E274= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs1384908497; called by muse, mutect2, varscan2
- AC007342.3 | n.681C>T | RNA (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- AC136604.1 | n.540C>T | RNA (SNP) | VAF 26/73 reads (36%) | catalogued as rs765677290; called by muse, mutect2, varscan2
- ALOX15 | c.*632T>C | 3'UTR (SNP) | VAF 4/8 reads (50%) | called by muse, mutect2, varscan2
- AP001042.1 | n.2509C>T | RNA (SNP) | VAF 12/58 reads (21%) | catalogued as rs1331822633; called by muse, mutect2, varscan2
- ATP5IF1 | chr1:28236111 C>G | 5'Flank (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- B3GAT2 | c.*4021A>C | 3'UTR (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- C2orf73 | c.*753A>C | 3'UTR (SNP) | VAF 26/47 reads (55%) | called by muse, mutect2, varscan2
- CACNG2 | c.-180G>T | 5'UTR (SNP) | VAF 20/54 reads (37%) | called by muse, mutect2, varscan2
- CLDN9 | c.-226C>T | 5'UTR (SNP) | VAF 8/67 reads (12%) | catalogued as rs529393711; called by muse, mutect2, varscan2
- CLU | c.*804C>T | 3'UTR (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- CSNK1G3 | c.*661A>T | 3'UTR (SNP) | VAF 16/40 reads (40%) | catalogued as rs1163758659; called by muse, mutect2, varscan2
- CTDSPL | c.426+435_426+448del | Intron (DEL) | VAF 42/133 reads (32%) | called by mutect2, pindel, varscan2
- DDX52 | c.*1433G>T | 3'UTR (SNP) | VAF 12/36 reads (33%) | catalogued as rs887395317; called by muse, mutect2, varscan2
- DHRS12 | c.844+415G>A | Intron (SNP) | VAF 18/35 reads (51%) | called by muse, mutect2, varscan2
- DNMT3A | c.-76G>C | 5'UTR (SNP) | VAF 15/78 reads (19%) | called by muse, mutect2, varscan2
- DPH6 | c.*115G>C | 3'UTR (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- ELAVL2 | chr9:23690421 A>C | 3'Flank (SNP) | VAF 21/30 reads (70%) | called by muse, mutect2, varscan2
- FRY | c.*320A>G | 3'UTR (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- GABRA4 | c.*1895T>C | 3'UTR (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- GALT | c.904+44T>G | Intron (SNP) | VAF 14/17 reads (82%) | called by muse, mutect2, varscan2
- GLRA3 | c.*6848A>C | 3'UTR (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- GPAT4 | c.*1583C>T | 3'UTR (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- GVINP1 | n.2514G>A | RNA (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- HAAO | c.*252C>A | 3'UTR (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- HDAC2 | c.*6150dup | 3'UTR (INS) | VAF 16/56 reads (29%) | catalogued as rs1357877918; called by mutect2, pindel, varscan2
- HNRNPH1 | c.-1207G>T | 5'UTR (SNP) | VAF 84/234 reads (36%) | called by muse, mutect2, varscan2
- HPGD | c.421+1919C>T | Intron (SNP) | VAF 10/14 reads (71%) | called by muse, mutect2, varscan2
- KCNC1 | c.*2305C>A | 3'UTR (SNP) | VAF 27/68 reads (40%) | called by muse, mutect2
- KHDRBS3 | c.*201A>T | 3'UTR (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- KIF13A | chr6:17759914 G>A | 3'Flank (SNP) | VAF 20/29 reads (69%) | called by muse, mutect2, varscan2
- LINC01235 | n.714A>T | RNA (SNP) | VAF 4/26 reads (15%) | called by muse, varscan2
- LNPEP | c.*2808G>T | 3'UTR (SNP) | VAF 29/54 reads (54%) | called by muse, mutect2, varscan2
- MARK1 | c.*1957T>A | 3'UTR (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
- MED9 | c.*183G>A | 3'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- MRPL19 | c.104-76T>C | Intron (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- MYL1 | c.-10A>T | 5'UTR (SNP) | VAF 20/39 reads (51%) | catalogued as rs757038593, COSV61681242; called by muse, mutect2, varscan2
- OTUD6B | c.*1869T>A | 3'UTR (SNP) | VAF 16/26 reads (62%) | called by muse, mutect2, varscan2
- P4HTM | c.724+130G>A | Intron (SNP) | VAF 27/48 reads (56%) | called by muse, mutect2, varscan2
- PCDHA10 | c.2388+4932C>T | Intron (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- PPP1R17 | c.*1026A>C | 3'UTR (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- PPP2R1B | c.*3282T>A | 3'UTR (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- PRSS37 | c.-313A>T | 5'UTR (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- PTCH1 | c.*1884C>T | 3'UTR (SNP) | VAF 10/29 reads (34%) | catalogued as rs557066042; called by mutect2, varscan2
- RBM15 | c.-74C>A | 5'UTR (SNP) | VAF 4/82 reads (5%) | called by muse, mutect2
- REST | c.*3556T>G | 3'UTR (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- RIMS1 | c.1679-20922G>A | Intron (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- SH3BGRL2 | c.*1754del | 3'UTR (DEL) | VAF 10/20 reads (50%) | catalogued as rs982815110; called by mutect2, varscan2
- TAFA5 | c.112+55098C>T | Intron (SNP) | VAF 13/40 reads (33%) | catalogued as COSV60998275; called by muse, mutect2, varscan2
- TBC1D31 | c.1033-1360A>T | Intron (SNP) | VAF 8/30 reads (27%) | called by mutect2, varscan2
- TENM3 | c.*226G>A | 3'UTR (SNP) | VAF 6/9 reads (67%) | called by muse, mutect2, varscan2
- TFCP2L1 | c.*5487G>T | 3'UTR (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- TGFBR1 | c.*4432G>T | 3'UTR (SNP) | VAF 16/52 reads (31%) | catalogued as rs1241885416; called by muse, mutect2, varscan2
- TNR | c.-37G>A | 5'UTR (SNP) | VAF 47/110 reads (43%) | catalogued as COSV54889993; called by muse, mutect2, varscan2
- TPGS2 | c.*90A>G | 3'UTR (SNP) | VAF 4/34 reads (12%) | catalogued as rs1476783583; called by muse, mutect2
- USP13 | c.*5040G>A | 3'UTR (SNP) | VAF 20/64 reads (31%) | catalogued as rs145820187; called by muse, mutect2, varscan2
- UVSSA | c.935-86A>T | Intron (SNP) | VAF 4/8 reads (50%) | called by muse, mutect2, varscan2
- YBX1P1 | n.78C>T | RNA (SNP) | VAF 5/11 reads (45%) | catalogued as rs760825525; called by muse, mutect2, varscan2
- ZNF43 | c.*407T>C | 3'UTR (SNP) | VAF 3/8 reads (38%) | called by muse, mutect2
